Somatic mutation profile of tumor specimen MMRF_1633_1_BM_CD138pos (aliquot MMRF_1633_1_BM_CD138pos_T1_KBS5U_L04307) from MMRF case MMRF_1633, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.3 years (19,842 days).
Specimen MMRF_1633_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a8ec4fc-b963-409d-a14a-599afa2d1230.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1633_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1633_1_PB_Whole_C3_KBS5U_L04318; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9df1d468-a6c1-462c-bf62-d2a190e96dcf

The open-access MAF lists 90 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 18, Intron 11, Silent 10, 5'UTR 4, 5'Flank 3, Nonsense Mutation 2, 3'Flank 2, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2
- ABCC9 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 64/144 reads (44%) | catalogued as rs1411357079, COSV53985920, COSV99688052; called by muse, mutect2, varscan2
- C19orf18 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs146255633, COSV58705690; called by muse, mutect2, varscan2
- CCDC171 | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52634599; called by muse, mutect2, varscan2
- CDK15 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774206560, COSV99642946; called by muse, mutect2, varscan2
- COL13A1 | c.1091C>T p.P364L (on ENST00000398978 / NM_001130103.2; = p.P307L on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1425795945, COSV62566953; called by muse, mutect2, varscan2
- DNER | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs370947900; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as rs1235110542; called by muse, mutect2
- GYS2 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767722149, COSV53928734; called by muse, mutect2, varscan2
- HCN4 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1170518463, COSV56081107; called by muse, mutect2
- IGHV2-70D | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1456429000; called by muse, mutect2
- IGHV2-70D | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194006557; called by muse, varscan2
- IGLV3-1 | c.46+1G>A p.X16_splice | Splice Site (SNP) | VAF 50/129 reads (39%) | catalogued as rs1478244621; called by muse, mutect2, varscan2
- MSH6 | c.1811A>G p.E604G | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV52278845; called by muse, mutect2
- MYH13 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs1418924623; called by muse, mutect2, varscan2
- MYO19 | c.415-1G>A p.X139_splice | Splice Site (SNP) | VAF 18/33 reads (55%) | catalogued as rs1373977528; called by muse, mutect2, varscan2
- PEAK1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56941720; called by muse, mutect2
- ZNF668 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 85/161 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs958178789, COSV56217589; called by muse, mutect2, varscan2
- CCDC22 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CLASRP | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CNNM3 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- COL4A6 | c.3696T>G p.G1232= | Splice Region (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- DDX60L | c.4535A>G p.Y1512C | Missense Mutation (SNP) | VAF 89/166 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DGKZ | c.24T>A p.H8Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2
- DNAAF4 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 54/664 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2
- EGR1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA12A | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- IGKJ2 | chr2:88861513 AAAAGTACTTACGTTTGATCTCCAGCTTGGTCCCCTGGCCAAAACTGC>CACAGGACCTACGTTTGATCTCCAGCTTGGTCCCCTGGCCAAAAGTTT | Missense Mutation (ONP) | VAF 4/50 reads (8%) | called by muse*, pindel, varscan2*
- MEGF6 | c.3415G>T p.A1139S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MIA3 | c.1322A>T p.D441V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- OR5AC2 | c.564A>T p.K188N | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PRKCI | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2
- PRPSAP2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2
- RALGAPA2 | c.1171G>C p.V391L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TENT5C | c.384_385del p.K128Nfs*22 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- TENT5C | c.652dup p.D218Gfs*3 | Frame Shift Ins (INS) | VAF 39/77 reads (51%) | called by mutect2, pindel, varscan2
- TENT5C | c.911dup p.Y304* | Nonsense Mutation (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- TLN1 | c.5951C>G p.A1984G | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2
- TRPM6 | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- WEE1 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF502 | c.1586G>T p.R529I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ADARB2 | c.1548C>T p.R516= | Silent (SNP) | VAF 44/77 reads (57%) | catalogued as rs772506968, COSV67214797; called by muse, mutect2, varscan2
- CACNA1C | c.300G>A p.P100= | Silent (SNP) | VAF 80/158 reads (51%) | catalogued as rs764323907, COSV100216030, COSV59762999; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HELZ | c.5403G>A p.P1801= | Silent (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.315C>T p.Y105= | Silent (SNP) | VAF 54/107 reads (50%) | catalogued as rs373828762; called by muse, mutect2, varscan2
- KREMEN2 | c.837G>A p.S279= | Silent (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2
- MYH1 | c.5184C>T p.I1728= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV99877245; called by muse, mutect2, varscan2
- NHSL2 | c.942C>T p.S314= (on ENST00000510661; = p.S680= on NM_001013627.2) | Silent (SNP) | VAF 91/203 reads (45%) | called by muse, mutect2, varscan2
- RLN1 | c.420C>T p.A140= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as rs576694797, COSV99802828; called by muse, mutect2, varscan2
- SGSM1 | c.1092G>A p.S364= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs758101180; called by muse, mutect2, varscan2
- TMEM126B | c.33G>A p.K11= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- AC073316.1 | n.825A>G | RNA (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2
- AP000769.3 | chr11:65503537 G>C | 5'Flank (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- BCAT2 | c.*169C>A | 3'UTR (SNP) | VAF 23/34 reads (68%) | called by muse, mutect2, varscan2
- CAMK2A | c.*33C>T | 3'UTR (SNP) | VAF 26/235 reads (11%) | catalogued as rs755226405, COSV62248413; called by muse, mutect2, varscan2
- CCSER1 | c.*909dup | 3'UTR (INS) | VAF 22/50 reads (44%) | called by mutect2, pindel, varscan2
- CCSER1 | c.*999T>G | 3'UTR (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- CDH6 | c.*4213A>G | 3'UTR (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- CRB1 | c.4005+1648G>A | Intron (SNP) | VAF 49/105 reads (47%) | catalogued as rs574983522; called by muse, mutect2, varscan2
- DLG3 | c.-23T>G | 5'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- FOXO3B | c.*465G>A | 3'UTR (SNP) | VAF 27/48 reads (56%) | catalogued as rs1160438398; called by muse, mutect2, varscan2
- IGLL5 | c.-40C>T | 5'UTR (SNP) | VAF 21/48 reads (44%) | catalogued as rs145696836, COSV73251009; called by muse, mutect2, varscan2
- IRAK3 | c.134-6107G>C | Intron (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- KCTD16 | c.*33del | 3'UTR (DEL) | VAF 48/80 reads (60%) | catalogued as rs376426438; called by mutect2, varscan2
- LTB | c.163-23G>A | Intron (SNP) | VAF 136/346 reads (39%) | catalogued as rs181617527; called by muse, mutect2, varscan2
- MAN2B2 | c.2815-1149G>A | Intron (SNP) | VAF 18/117 reads (15%) | catalogued as rs757562488; called by muse, mutect2, varscan2
- MTERF1 | c.*578A>T | 3'UTR (SNP) | VAF 67/205 reads (33%) | called by muse, mutect2, varscan2
- P3H2 | c.1230-44T>G | Intron (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- PAM16 | c.-38G>A | 5'UTR (SNP) | VAF 14/36 reads (39%) | catalogued as rs780660624; called by muse, mutect2, varscan2
- PCNX4 | c.689+2127G>T | Intron (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- PRMT9 | c.*55C>A | 3'UTR (SNP) | VAF 28/172 reads (16%) | catalogued as COSV56855228; called by muse, mutect2, varscan2
- PRR27 | c.-54C>T | 5'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as rs909928081, COSV60640515; called by muse, mutect2
- PTMA | c.117+27C>A | Intron (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- RNA5SP283 | chr9:62801499 C>G | 3'Flank (SNP) | VAF 9/86 reads (10%) | catalogued as rs1045866847; called by muse, mutect2, varscan2
- SEMA5A | c.*4036C>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- SERPINB13 | c.*526T>G | 3'UTR (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- SGK1 | chr6:134175591 C>T | 5'Flank (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- SHTN1 | c.*1392G>A | 3'UTR (SNP) | VAF 72/145 reads (50%) | catalogued as rs1564857583; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.*120T>G | 3'UTR (SNP) | VAF 59/110 reads (54%) | called by muse, mutect2, varscan2
- SORBS2 | c.*1598G>A | 3'UTR (SNP) | VAF 52/91 reads (57%) | catalogued as rs1247389001; called by muse, mutect2, varscan2
- TAGAP | c.-58-131A>C | Intron (SNP) | VAF 16/30 reads (53%) | called by mutect2, varscan2
- TFCP2L1 | c.*3214A>G | 3'UTR (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- TNRC6A | c.*2339C>T | 3'UTR (SNP) | VAF 41/100 reads (41%) | catalogued as rs778408080; called by muse, mutect2, varscan2
- TOX3 | c.87+27081A>C | Intron (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- TRDN | c.794-1356C>G | Intron (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- TRIM2 | chr4:153338098 A>C | 3'Flank (SNP) | VAF 57/123 reads (46%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331239 C>T | 5'Flank (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- TUSC3 | c.*1035A>G | 3'UTR (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- WRAP73 | c.340-31T>A | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- ZFX | c.*4002G>A | 3'UTR (SNP) | VAF 18/64 reads (28%) | catalogued as rs937325679; called by muse, mutect2, varscan2
